Somatic mutation profile of tumor specimen TCGA-E1-A7YN-01A (aliquot TCGA-E1-A7YN-01A-11D-A34A-08) from TCGA case TCGA-E1-A7YN, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 63.5 years (23,180 days).
Specimen TCGA-E1-A7YN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a8b8ea6-8397-49bd-b07e-fa4cc6ebc13a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YN-10A (Blood Derived Normal), aliquot TCGA-E1-A7YN-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19a604b6-c3ce-445d-bb9f-b1f9be0b6d23

The open-access MAF lists 70 somatic variants for this specimen: 50 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 18, Nonsense Mutation 5, Frame Shift Del 2, Intron 1, RNA 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH2 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs794728395, CM148552, COSV100060207, COSV51126119; ClinVar: likely pathogenic; called by muse, mutect2
- ABCB1 | c.932C>A p.A311D | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99713051; called by muse, mutect2, varscan2
- ABCC11 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs371616371; called by muse, mutect2, varscan2
- ADGRF4 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs1420124125, COSV51951926; called by muse, mutect2, varscan2
- AFG1L | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs186208029; called by muse, mutect2, varscan2
- ANKMY1 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs778075994, COSV99802162; called by muse, mutect2, varscan2
- ANKRD11 | c.4093C>T p.R1365* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV56353701; called by muse, mutect2, varscan2
- CAMK2A | c.302T>C p.I101T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100804509; called by muse, mutect2, varscan2
- CNTN4 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.408); catalogued as COSV101281356; called by muse, mutect2, varscan2
- COL11A2 | c.1963G>A p.G655R (on ENST00000341947 / NM_080680.3; = p.G548R on NM_080679.2) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100554008; called by muse, mutect2, varscan2
- CRPPA | c.464A>T p.H155L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755183657, COSV101235391; called by muse, mutect2, varscan2
- CRX | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs761797993, COSV99704477; called by muse, mutect2, varscan2
- CYP3A4 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as COSV100315655; called by muse, mutect2, varscan2
- DCX | c.404del p.K135Rfs*16 | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | catalogued as CD087671; called by mutect2, pindel, varscan2
- DDI1 | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs371239684, COSV100160769, COSV56374601; called by muse, mutect2
- DNAH2 | c.1837C>T p.R613W | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs373159496, COSV50019564; called by muse, mutect2
- DNAH9 | c.3268C>T p.R1090* | Nonsense Mutation (SNP) | VAF 24/183 reads (13%) | catalogued as rs764052121, COSV52339207; called by muse, mutect2, varscan2
- DSG1 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57138805, COSV99936013; called by muse, mutect2, varscan2
- FES | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs779752765, COSV61000217; called by muse, mutect2
- FGF14 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as rs757879324, COSV65935613; called by muse, mutect2, varscan2
- FRAS1 | c.10357G>A p.V3453I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.636); catalogued as rs376389651; called by mutect2, varscan2
- GAS7 | c.853G>A p.E285K (on ENST00000432992 / NM_201433.2; = p.E145K on NM_003644.3) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs754726154, COSV100095476; called by muse, mutect2, varscan2
- HKDC1 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as rs1053421576, COSV100664547; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV61142900; called by muse, mutect2, varscan2
- KAT5 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753132884, COSV100383916, COSV100384084; called by muse, mutect2, varscan2
- LAMB1 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766126287, COSV55971905; called by muse, mutect2, varscan2
- MNDA | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as rs767300186, COSV100933446, COSV63742115; called by muse, mutect2, varscan2
- MS4A7 | c.173T>G p.L58W | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV100279528; called by muse, mutect2, varscan2
- MYO1A | c.3100G>T p.G1034W | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100270936; called by muse, mutect2, varscan2
- MYO6 | c.2680C>G p.Q894E | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100889350; called by muse, mutect2
- OPN1LW | c.831C>G p.Y277* | Nonsense Mutation (SNP) | VAF 55/277 reads (20%) | catalogued as COSV100885036; called by muse, mutect2, varscan2
- OR2L3 | c.392A>T p.Y131F | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100741970; called by muse, mutect2, varscan2
- OR4X2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100183240; called by muse, mutect2
- OTOP2 | c.680T>A p.L227H | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); catalogued as COSV100508892; called by muse, mutect2, varscan2
- SH3RF2 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as rs376743854; called by muse, mutect2, varscan2
- SLCO1B1 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs376060151; called by muse, mutect2, varscan2
- SPTA1 | c.3359T>A p.F1120Y | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs376284347; called by muse, mutect2, varscan2
- TEK | c.3008G>A p.R1003H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773518368, COSV66230879; called by muse, mutect2, varscan2
- TMEM52 | c.529C>G p.P177A | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV100205555; called by muse, mutect2
- TTN | c.12338T>A p.V4113E (on ENST00000591111; = p.V4067E on NM_003319.4) | Missense Mutation (SNP) | VAF 21/125 reads (17%) | catalogued as COSV100612440; called by muse, mutect2, varscan2
- TXNDC15 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs769032888, COSV100613564; called by muse, mutect2, varscan2
- UFSP2 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as COSV99249095; called by muse, mutect2, varscan2
- UNC5C | c.994T>C p.C332R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101497903; called by muse, mutect2, varscan2
- XKR7 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs781492828, COSV101629259; called by muse, mutect2, varscan2
- ZNF473 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs575531440, COSV99568819; called by muse, mutect2, varscan2
- ZNF777 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs201502980, COSV56099608; called by muse, mutect2, varscan2
- CFAP69 | c.1982_1986del p.L661* | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- DST | c.19093dup p.T6365Nfs*23 (on ENST00000361203 / NM_001374722.1; = p.T4062Nfs*23 on NM_015548.5) | Frame Shift Ins (INS) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- FRG2C | c.177A>C p.Q59H | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by muse, mutect2
- SMR3A | c.181G>T p.G61W | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCC1 | c.1749C>T p.F583= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as rs1325918780, COSV60693310; called by muse, varscan2
- BMP3 | c.741C>T p.A247= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as rs1007409366, COSV51095745; called by muse, mutect2, varscan2
- CATSPER1 | c.1884G>A p.T628= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs370158610; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EYA4 | c.867G>A p.T289= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs763899252, COSV62050744; called by muse, mutect2, varscan2
- LRP2 | c.8778C>T p.D2926= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as rs199845695, COSV99788436; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MS4A6A | c.126C>T p.H42= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as rs113133013, COSV60617004; called by muse, mutect2, varscan2
- MUC15 | c.828C>T p.D276= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as rs748244834, COSV55554403; called by muse, mutect2, varscan2
- NEFM | c.144G>C p.V48= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV55330457, COSV99647289; called by muse, mutect2, varscan2
- NSD3 | c.1353C>T p.S451= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV100388653; called by muse, mutect2, varscan2
- PITPNM3 | c.1017G>A p.P339= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs768613943, COSV52597011; called by muse, mutect2, varscan2
- PNMA3 | c.1179A>T p.R393= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100937603; called by muse, mutect2, varscan2
- PPM1N | c.601C>A p.R201= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs772491110, COSV99838947; called by muse, varscan2
- RBFOX1 | c.480C>T p.F160= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as rs919248039, COSV60946947; called by muse, mutect2, varscan2
- SPESP1 | c.246C>T p.D82= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs757784904, COSV99533855; called by muse, mutect2, varscan2
- SPTBN5 | c.4791C>T p.I1597= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs771940150, COSV100312374, COSV58024198; called by mutect2, varscan2
- TAF1L | c.3459G>A p.L1153= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV99644695; called by muse, mutect2, varscan2
- TRPV5 | c.1863C>T p.C621= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs745910533, COSV54686433; called by muse, mutect2, varscan2
- ZXDB | c.1350C>T p.G450= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as rs755704080, COSV100885922; called by muse, mutect2, varscan2
- MACF1 | c.15832-10033_15832-10030del | Intron (DEL) | VAF 6/55 reads (11%) | catalogued as rs746949070; called by mutect2, pindel
- TUBB7P | n.1091C>T | RNA (SNP) | VAF 33/202 reads (16%) | called by muse, varscan2
